Somatic mutation profile of tumor specimen TCGA-EM-A4FN-01A (aliquot TCGA-EM-A4FN-01A-11D-A257-08) from TCGA case TCGA-EM-A4FN, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 49.8 years (18,185 days).
Specimen TCGA-EM-A4FN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a249787-ebd7-43bb-bf25-6b5556cd054b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A4FN-10A (Blood Derived Normal), aliquot TCGA-EM-A4FN-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a20e8b7e-e606-4c58-888f-b647d7b6d008

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AGFG1 | c.1157C>A p.S386Y | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.355); catalogued as COSV100028821; called by muse, mutect2, varscan2
- ARID2 | c.4723del p.Q1575Sfs*51 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | catalogued as COSV57595513; called by mutect2, pindel
- BTN3A3 | c.893C>A p.T298K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99764896; called by muse, mutect2, varscan2
- LIPK | c.271A>G p.S91G | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV101344981; called by muse, mutect2, varscan2
- LMO7 | c.4587T>A p.S1529R (on ENST00000357063; = p.S1210R on NM_005358.5) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100413250; called by muse, mutect2, varscan2
- RIMS1 | c.4958T>A p.I1653N | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99327186; called by muse, mutect2, varscan2
- TPO | c.1951C>T p.P651S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749796672, COSV100221143; called by muse, mutect2, varscan2
- TRIM11 | c.686T>A p.I229N | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV99488432; called by muse, varscan2
- AHNAK2 | c.8160C>T p.H2720= | Silent (SNP) | VAF 88/189 reads (47%) | catalogued as rs373499038; called by muse, mutect2, varscan2
- ECEL1 | c.1779C>T p.Y593= | Silent (SNP) | VAF 52/137 reads (38%) | catalogued as rs552489480, COSV100458750; ClinVar: likely benign; called by muse, mutect2, varscan2
- GRIA4 | c.558G>T p.V186= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV99231706; called by muse, mutect2, varscan2
- PHLPP1 | c.4461C>T p.S1487= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV99408352; called by muse, mutect2
- ETV1 | c.45+300G>A | Intron (SNP) | VAF 42/121 reads (35%) | catalogued as COSV99623551; called by muse, mutect2, varscan2
